Somatic mutation profile of tumor specimen TCGA-78-7542-01A (aliquot TCGA-78-7542-01A-21D-2063-08) from TCGA case TCGA-78-7542, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.8 years (20,763 days).
Specimen TCGA-78-7542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9469a1e-f810-4c0c-975e-1e82257ff032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7542-11A (Solid Tissue Normal), aliquot TCGA-78-7542-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a350afa2-198c-4462-8625-ba2410d823fe

The open-access MAF lists 398 somatic variants for this specimen: 293 protein-altering or splice-affecting, 97 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 97, Nonsense Mutation 21, Frame Shift Del 10, Splice Site 5, RNA 4, Frame Shift Ins 3, 3'UTR 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA2 | c.2746G>T p.V916L (on ENST00000614293; = p.V886L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.174); catalogued as COSV99686807; called by muse, mutect2
- ABCA5 | c.4039G>T p.V1347F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV67018229; called by muse, mutect2, varscan2
- ABCG2 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199772868, COSV52947986; called by muse, mutect2, varscan2
- ACVRL1 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as CM050032, COSV66360677; called by muse, mutect2, varscan2
- ADA | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs371353841; called by muse, mutect2, varscan2
- ADAM29 | c.1379A>T p.N460I | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63666258; called by muse, mutect2, varscan2
- ADAMTS12 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1443758745, COSV100710456, COSV61257608, COSV61272417; called by muse, mutect2
- ADAMTS12 | c.2138G>T p.G713V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61263490, COSV61272426; called by muse, mutect2, varscan2
- ADAMTS12 | c.588G>T p.R196S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100710230, COSV100711686; called by muse, mutect2, varscan2
- ADAMTS12 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs779295680, COSV100710233; called by muse, mutect2, varscan2
- ADAMTS14 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV64604809; called by muse, mutect2, varscan2
- ADGRA3 | c.1880G>T p.R627I | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.201); catalogued as COSV99292875; called by muse, mutect2, varscan2
- ADGRE1 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as COSV51678904; called by muse, mutect2, varscan2
- AHNAK | c.8554G>T p.D2852Y | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57223867; called by muse, mutect2, varscan2
- AKAP6 | c.4933C>T p.P1645S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55225376; called by muse, mutect2, varscan2
- AKNAD1 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV62201632; called by muse, mutect2, varscan2
- AL136295.1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs371123322; called by muse, mutect2, varscan2
- ANKRD16 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV51947271; called by muse, mutect2, varscan2
- ANKRD30A | c.4024A>T p.K1342* (on ENST00000611781; = p.K1286* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV64616671; called by muse, mutect2, varscan2
- APOB | c.12495G>T p.Q4165H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV51945549; called by muse, mutect2, varscan2
- APOBEC4 | c.60C>A p.Y20* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV58018236; called by muse, mutect2, varscan2
- ATP10D | c.951A>T p.R317S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV56710955; called by muse, mutect2, varscan2
- BAHCC1 | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs557626485, COSV57031019; called by muse, mutect2, varscan2
- BBOX1 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54192907; called by muse, mutect2, varscan2
- BCL11B | c.1736C>A p.A579E (on ENST00000357195 / NM_001282237.2; = p.A508E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61737854; called by muse, mutect2, varscan2
- BEND6 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV66069795; called by muse, mutect2, varscan2
- BOD1L1 | c.4144G>T p.V1382L | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50036104; called by muse, mutect2, varscan2
- BPIFB2 | c.669+1G>A p.X223_splice | Splice Site (SNP) | VAF 45/60 reads (75%) | catalogued as rs761856259, COSV50068483, COSV50072410; called by muse, mutect2, varscan2
- BPTF | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58843287; called by muse, mutect2
- BRIP1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52005287; called by muse, mutect2, varscan2
- BTNL2 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100896015, COSV66631462; called by muse, mutect2, varscan2
- C1orf158 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.349); catalogued as COSV55347504; called by muse, mutect2, varscan2
- C1orf94 | c.1784G>T p.G595V (on ENST00000488417 / NM_001134734.2; = p.G405V on NM_032884.5) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64914862; called by muse, mutect2, varscan2
- C8orf34 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as COSV61373165, COSV61389401; called by muse, mutect2
- CACNB4 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV52399327; called by muse, mutect2, varscan2
- CADM3 | c.185G>C p.W62S (on ENST00000368125 / NM_001127173.3; = p.W96S on NM_021189.5) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930398, COSV63686674; called by muse, mutect2
- CASS4 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as COSV100824867, COSV64387723; called by muse, mutect2, varscan2
- CDH10 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52590962; called by muse, mutect2, varscan2
- CDH15 | c.2404C>G p.P802A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57026191; called by muse, mutect2, varscan2
- CENPF | c.5100G>T p.Q1700H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV65277402; called by muse, mutect2, varscan2
- CFAP77 | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58014480; called by muse, mutect2, varscan2
- CHRM3 | c.759G>T p.R253S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55097305, COSV55106778; called by muse, mutect2, varscan2
- CLTCL1 | c.4370G>A p.S1457N | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54236016; called by muse, mutect2, varscan2
- CMYA5 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 38/78 reads (49%) | catalogued as COSV71408167; called by muse, mutect2, varscan2
- CNGA3 | c.1711A>T p.I571F | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV55626493; called by muse, mutect2, varscan2
- CNOT10 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV59393942; called by muse, mutect2, varscan2
- COL11A1 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62190932; called by muse, mutect2, varscan2
- COL12A1 | c.7999T>A p.Y2667N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV59403038; called by muse, mutect2, varscan2
- COL22A1 | c.2680C>A p.Q894K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.475); catalogued as COSV57321840, COSV57351023; called by muse, mutect2, varscan2
- COL6A6 | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62032643; called by muse, mutect2, varscan2
- CPS1 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV51819022; called by muse, mutect2, varscan2
- CPSF7 | c.1359A>T p.Q453H (on ENST00000394888 / NM_001136040.4; = p.Q496H on NM_024811.4) | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV61212345; called by muse, mutect2
- CPXM2 | c.1392G>T p.W464C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53867530; called by muse, mutect2, varscan2
- CPZ | c.544T>G p.F182V (on ENST00000360986 / NM_001014447.3; = p.F171V on NM_003652.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59924608; called by muse, varscan2
- CRHR1 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99523254; called by muse, mutect2, varscan2
- CRHR1 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99523256; called by muse, mutect2, varscan2
- CRYGC | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52205819; called by muse, mutect2, varscan2
- CSMD1 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV68236122; called by muse, mutect2, varscan2
- CSMD3 | c.9026A>T p.E3009V (on ENST00000297405 / NM_001363185.1; = p.E2840V on NM_052900.3) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV52263853; called by muse, mutect2, varscan2
- CSRNP3 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV58783202, COSV58786166; called by muse, mutect2, varscan2
- CYP2S1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs372019122; called by muse, mutect2
- DAW1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV59367534, COSV59367551; called by muse, mutect2, varscan2
- DCAF8 | c.1709A>G p.D570G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as COSV58785271; called by muse, mutect2, varscan2
- DCDC1 | c.4925C>A p.S1642Y (on ENST00000597505 / NM_001367979.1; = p.S749Y on NM_020869.3) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV58001689; called by muse, mutect2, varscan2
- DCDC1 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV60856894; called by muse, mutect2
- DCLK3 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV69364149; called by muse, mutect2, varscan2
- DCSTAMP | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52579148; called by muse, mutect2, varscan2
- DHX57 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV54889050; called by muse, mutect2, varscan2
- DIXDC1 | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59462881; called by muse, mutect2, varscan2
- DLC1 | c.118T>A p.L40M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.759); catalogued as COSV52318775; called by muse, mutect2, varscan2
- DLGAP3 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV52396192; called by muse, mutect2, varscan2
- DNPEP | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56111523; called by muse, varscan2
- DOCK10 | c.4442A>T p.N1481I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51422722; called by muse, mutect2
- DSC1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758323245, COSV57149175; called by muse, mutect2, varscan2
- DSC2 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51867461; called by muse, mutect2, varscan2
- EBF3 | c.1399G>C p.V467L (on ENST00000355311 / NM_001375392.1; = p.V458L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV62479009, COSV62482987; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1233C>A p.F411L (on ENST00000361735 / NM_015935.5; = p.F325L on NM_014955.3) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV100675757; called by muse, mutect2
- EIF4G1 | c.3097G>A p.G1033S (on ENST00000346169 / NM_198241.3; = p.G838S on NM_004953.5) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs1424493002, COSV59992673; called by muse, mutect2, varscan2
- ENAM | c.3022A>C p.N1008H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV68536666; called by muse, mutect2, varscan2
- EPHA5 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs772410607, COSV99895911; called by muse, mutect2, varscan2
- EPHA6 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101063111, COSV67585991; called by muse, mutect2, varscan2
- EPHA6 | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.672); catalogued as COSV67585999; called by muse, mutect2, varscan2
- F12 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as rs774768505, COSV53692327; called by muse, mutect2
- FAM135B | c.4049T>A p.L1350Q | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52742766; called by muse, varscan2
- FAM135B | c.1909C>A p.P637T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52742780; called by muse, mutect2, varscan2
- FAM149A | c.1507G>A p.V503I (on ENST00000356371 / NM_001367768.2; = p.V212I on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs773535952, COSV57029369; called by muse, mutect2, varscan2
- FAM47B | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV61455901; called by muse, mutect2, varscan2
- FAM71E1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV58542887; called by muse, mutect2, varscan2
- FANCI | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55531324; called by muse, mutect2, varscan2
- FCGR2B | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52682617; called by muse, mutect2
- FGFBP2 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769956704, COSV52588366; called by muse, mutect2, varscan2
- FLG | c.6997C>A p.H2333N | Missense Mutation (SNP) | VAF 147/711 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as COSV64245533; called by muse, mutect2, varscan2
- FLG2 | c.3838G>A p.V1280M | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV66171210; called by muse, mutect2, varscan2
- FLT3 | c.2648C>A p.S883* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | catalogued as COSV54056198, COSV54063265; called by muse, mutect2, varscan2
- FMN2 | c.1967G>C p.R656P | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV60421300, COSV60444052; called by muse, mutect2, varscan2
- FMR1NB | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); catalogued as COSV65072689; called by muse, mutect2, varscan2
- FOXP1 | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59549354; called by muse, mutect2, varscan2
- FRMD3 | c.473-2A>T p.X158_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV58466378; called by muse, mutect2
- FRS3 | c.771G>T p.Q257H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.378); catalogued as COSV52485855; called by muse, mutect2, varscan2
- FSHR | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58630283; called by muse, mutect2, varscan2
- GABRB3 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV54676484; called by muse, mutect2, varscan2
- GABRQ | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.341); catalogued as COSV64783350; called by muse, mutect2, varscan2
- GAL3ST2 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as rs201607018, COSV51951125; called by muse, mutect2, varscan2
- GC | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV56738753; called by muse, mutect2, varscan2
- GLDC | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833582, CM061014, COSV58683216; called by muse, mutect2, varscan2
- GLT8D1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs770950923, COSV56478179; called by muse, mutect2, varscan2
- GPR139 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58504153; called by muse, mutect2, varscan2
- GPR6 | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV51572992; called by muse, mutect2, varscan2
- GRID1 | c.1991C>A p.P664H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60043496; called by muse, mutect2, varscan2
- GRIK1 | c.2699G>A p.G900D | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.159); catalogued as rs1007750195, COSV58726986; called by muse, mutect2, varscan2
- GRM3 | c.1200G>T p.M400I | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV64476861; called by muse, mutect2, varscan2
- H2BC5 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56802804; called by muse, mutect2
- HAND2 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs759798066, COSV64018713; called by muse, mutect2, varscan2
- HEPH | c.2101G>T p.A701S (on ENST00000343002; = p.A434S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs199531324, COSV57965004, COSV57968960; called by muse, mutect2, varscan2
- HRC | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53257956; called by muse, mutect2, varscan2
- HSD3B1 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52491692; called by muse, mutect2, varscan2
- HSPA8 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57085256; called by muse, mutect2, varscan2
- ICE1 | c.1535G>T p.R512I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56829438; called by muse, mutect2, varscan2
- IQCG | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99502007; called by muse, mutect2, varscan2
- IQCG | c.1327A>T p.K443* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as rs1560075620, COSV99502009; called by muse, mutect2, varscan2
- IRS4 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 102/142 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64535232; called by muse, mutect2, varscan2
- ITGB3 | c.1799T>A p.L600Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV71384828; called by muse, mutect2, varscan2
- KCNK13 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV56415544; called by muse, mutect2, varscan2
- KCNQ2 | c.2324G>T p.R775M (on ENST00000359125 / NM_172107.4; = p.R747M on NM_004518.6) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV60550454; called by muse, mutect2, varscan2
- KCNT2 | c.2572C>A p.L858I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV54097421; called by muse, mutect2, varscan2
- KCNT2 | c.1540C>A p.H514N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV54097444; called by muse, mutect2, varscan2
- KCTD8 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917687346, COSV63593374; called by muse, mutect2, varscan2
- KIF21B | c.1946T>A p.L649Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59762945; called by muse, mutect2, varscan2
- KLHL14 | c.1167C>A p.H389Q | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV63834446; called by muse, mutect2, varscan2
- KRTAP6-3 | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | PolyPhen benign (0.291); catalogued as COSV66962894; called by muse, mutect2, varscan2
- KRTAP9-8 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 36/156 reads (23%) | catalogued as COSV54200621, COSV99565800; called by muse, varscan2
- KSR2 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs534046978, COSV56676747; called by muse, mutect2, varscan2
- LAMA1 | c.8516G>T p.G2839V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67541409, COSV67542914; called by muse, mutect2, varscan2
- LGALS12 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55371454, COSV99736754; called by muse, mutect2, varscan2
- LLCFC1 | c.229C>A p.Q77K (on ENST00000458732; = p.Q46K on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); catalogued as COSV62336784; called by muse, mutect2, varscan2
- LPIN2 | c.870T>G p.I290M | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV55242450; called by muse, mutect2
- LSG1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54571865; called by muse, mutect2, varscan2
- LY9 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.493); catalogued as COSV54433122, COSV54436309; called by muse, mutect2, varscan2
- MAD1L1 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56242672; called by muse, mutect2, varscan2
- MAD1L1 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV56242681; called by muse, mutect2, varscan2
- MAGEC3 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV53577736, COSV68924086; called by muse, mutect2, varscan2
- MBTPS1 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58571918; called by muse, mutect2, varscan2
- MCHR2 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373216169; called by muse, mutect2, varscan2
- MED23 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV63435314; called by muse, mutect2, varscan2
- MMP8 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52633761; called by muse, mutect2, varscan2
- MN1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV56558864, COSV56560639; called by muse, mutect2, varscan2
- MPPE1 | c.679-1G>T p.X227_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV57883213; called by muse, mutect2, varscan2
- MRTFB | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV57960098; called by muse, mutect2
- MTMR14 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372538745; called by muse, mutect2, varscan2
- MUC6 | c.1540A>T p.I514F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV101424392; called by muse, mutect2, varscan2
- MYO3A | c.3812T>C p.V1271A | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV56341974; called by muse, varscan2
- MYO3A | c.3855G>T p.L1285F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV56341987; called by muse, varscan2
- NANOG | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV57552176; called by muse, mutect2, varscan2
- NAV2 | c.3356G>A p.R1119Q (on ENST00000396087 / NM_001244963.2; = p.R1096Q on NM_145117.5) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs146962426; called by muse, mutect2
- NCAN | c.1073-2A>T p.X358_splice | Splice Site (SNP) | VAF 40/91 reads (44%) | catalogued as COSV53055551; called by muse, mutect2, varscan2
- NCOR2 | c.6644G>T p.G2215V | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV62301594; called by muse, mutect2, varscan2
- NEURL1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63915285; called by muse, mutect2
- NLGN1 | c.2360C>G p.T787S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.076); catalogued as COSV64342087; called by muse, mutect2, varscan2
- NLRP13 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61623379; called by muse, mutect2, varscan2
- NLRP14 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100204503; called by muse, mutect2, varscan2
- NLRP14 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV100204507, COSV55064901; called by muse, mutect2, varscan2
- NLRP7 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV60178758; called by muse, mutect2, varscan2
- NMT2 | c.1339A>T p.K447* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV65382844; called by muse, mutect2, varscan2
- NOL4 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52355635; called by muse, mutect2, varscan2
- NPHS1 | c.2660C>A p.P887H | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62289228; called by muse, mutect2, varscan2
- NPM2 | c.346A>T p.S116C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV57076272; called by mutect2, varscan2
- NPR3 | c.1211T>A p.V404E | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54091195; called by muse, mutect2, varscan2
- NSMCE3 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV54281780; called by muse, mutect2, varscan2
- NTRK3 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58134909; called by muse, mutect2, varscan2
- OR10J1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71128653; called by muse, mutect2, varscan2
- OR11H1 | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53272369, COSV99421975; called by muse, mutect2, varscan2
- OR14A16 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62927186, COSV62927581; called by muse, mutect2, varscan2
- OR2A25 | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV68717504; called by muse, mutect2
- OR2T1 | c.727C>G p.H243D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV63542536; called by muse, mutect2, varscan2
- OR2T12 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV58776956, COSV58778767; called by muse, mutect2
- OR52R1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100617799, COSV61888998; called by muse, mutect2
- OR7A17 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as rs765505909, COSV100541560, COSV100541649, COSV59415041; called by muse, mutect2, varscan2
- OR8G2P | c.379T>G p.C127G | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs781699619; called by muse, mutect2, varscan2
- OR8S1 | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | PolyPhen possibly damaging (0.608); catalogued as COSV59600405; called by muse, mutect2, varscan2
- PCDH15 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57267096, COSV57362650; called by muse, mutect2, varscan2
- PCDHA7 | c.1319G>T p.S440I | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); catalogued as COSV65346242; called by muse, mutect2, varscan2
- PCDHB11 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61309681, COSV61313644; called by muse, mutect2, varscan2
- PCDHB3 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV50605047; called by muse, mutect2, varscan2
- PCDHB5 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV50661080; called by muse, mutect2, varscan2
- PDSS2 | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64649407; called by muse, mutect2, varscan2
- PELO | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV50891235; called by muse, mutect2
- PEX5L | c.1537C>A p.R513S | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55846139, COSV99829535; called by muse, mutect2, varscan2
- PEX5L | c.1536C>A p.N512K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99827844; called by muse, mutect2, varscan2
- PGR | c.1973A>G p.Q658R | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1565339048, COSV54807435; called by muse, mutect2, varscan2
- PHGDH | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV65571882; called by muse, mutect2, varscan2
- PHOX2B | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56930893; called by muse, mutect2, varscan2
- PIKFYVE | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52246182; called by muse, mutect2, varscan2
- PLEKHA7 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs763048339, COSV63049109; called by muse, mutect2, varscan2
- PNMA5 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 72/95 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62626018; called by muse, mutect2, varscan2
- PNPLA6 | c.3103C>T p.R1035W (on ENST00000414982 / NM_001166111.2; = p.R987W on NM_006702.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55382622; called by muse, mutect2, varscan2
- POLR2B | c.2645G>C p.S882T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as COSV58901944; called by muse, mutect2, varscan2
- PPIL3 | c.306C>A p.F102L (on ENST00000392283 / NM_130906.3; = p.F106L on NM_032472.4) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV53769922; called by muse, mutect2, varscan2
- PRAM1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1568316648, COSV55315770; called by muse, mutect2, varscan2
- PRKG1 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs754799133, COSV64803460; called by muse, mutect2, varscan2
- PRMT7 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1293882145, COSV59834680; called by muse, mutect2, varscan2
- PRUNE2 | c.3419A>G p.D1140G | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.976); catalogued as COSV65044992; called by muse, mutect2, varscan2
- PTCRA | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100485696; called by muse, mutect2, varscan2
- PTCRA | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs754349321, COSV100485697; called by muse, mutect2, varscan2
- PTGS1 | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs199627452; called by muse, mutect2, varscan2
- PTMA | c.241G>T p.E81* (on ENST00000341369 / NM_001099285.2; = p.E80* on NM_002823.5) | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV58187781; called by muse, mutect2, varscan2
- PTPN5 | c.975G>C p.K325N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62127626, COSV62128222; called by muse, mutect2, varscan2
- R3HCC1L | c.2105T>C p.M702T (on ENST00000612478 / NM_001256619.2; = p.M688T on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV54403852; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV52790084; called by muse, mutect2, varscan2
- RBAK | c.1631G>T p.C544F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62332099; called by muse, mutect2, varscan2
- RBM12 | c.1829A>G p.N610S | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV58293659; called by muse, mutect2, varscan2
- RELN | c.6301G>A p.G2101R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59023553; called by muse, mutect2, varscan2
- RFPL3 | c.311A>G p.K104R (on ENST00000249007 / NM_001098535.1; = p.K75R on NM_006604.2) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV50751415; called by muse, mutect2, varscan2
- RHOA | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69041889, COSV69043206; called by muse, mutect2, varscan2
- RNF40 | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1186944152, COSV61215987; called by muse, mutect2, varscan2
- RORA | c.316A>T p.T106S (on ENST00000335670 / NM_134261.3; = p.T131S on NM_002943.3) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55042459; called by muse, mutect2, varscan2
- RP1L1 | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV61446874; called by muse, mutect2, varscan2
- RSPH3 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.026); catalogued as COSV51924127; called by muse, mutect2, varscan2
- SEC14L5 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV52040541; called by muse, mutect2, varscan2
- SIGLEC10 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV59484959; called by muse, mutect2, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1L2 | c.3069G>T p.Q1023H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53395924; called by muse, mutect2, varscan2
- SLC25A23 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV51194503; called by muse, mutect2, varscan2
- SLC8A1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60491174; called by muse, mutect2, varscan2
- SLC9B2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV60021056; called by muse, mutect2, varscan2
- SLFN11 | c.2605C>A p.H869N | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57699901; called by muse, mutect2, varscan2
- SNTG1 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV52460850; called by muse, mutect2, varscan2
- SORCS1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as COSV53890482, COSV99548516; called by muse, mutect2, varscan2
- SOX11 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58987239; called by muse, mutect2, varscan2
- SPAG9 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56240444; called by muse, mutect2, varscan2
- SPANXN1 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65123060; called by muse, mutect2, varscan2
- SPATA17 | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV65124920; called by muse, mutect2, varscan2
- SPATA31D1 | c.1333A>T p.N445Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61199020; called by muse, mutect2
- STAR | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV52418131; called by muse, varscan2
- STX16 | c.726G>T p.Q242H (on ENST00000371141 / NM_001001433.3; = p.Q221H on NM_003763.6) | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.161); catalogued as COSV56607448; called by muse, mutect2, varscan2
- SUGP1 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55923059; called by muse, mutect2, varscan2
- SYN3 | c.1489A>G p.N497D | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV60513303; called by muse, mutect2
- SYNPO2 | c.3587G>T p.R1196M | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV61113749; called by muse, mutect2, varscan2
- TAB2 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV53854323; called by muse, mutect2, varscan2
- TBC1D8B | c.1389A>G p.I463M | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.581); catalogued as COSV52181797; called by muse, mutect2, varscan2
- TCHHL1 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV64286761; called by muse, mutect2, varscan2
- TENT5B | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV56693566; called by muse, mutect2, varscan2
- TFEC | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.948); catalogued as COSV55401518, COSV55404595; called by muse, mutect2, varscan2
- TMEM74B | c.433del p.R145Vfs*10 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | catalogued as COSV67891874; called by mutect2, pindel, varscan2
- TMPRSS11A | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV58360149; called by muse, mutect2, varscan2
- TNRC6A | c.4721A>T p.Y1574F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59368177; called by muse, mutect2, varscan2
- TOR3A | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61679637; called by muse, mutect2, varscan2
- TP53I11 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100370803; called by muse, mutect2
- TPTE | c.1304T>C p.I435T (on ENST00000618007 / NM_199261.4; = p.I417T on NM_199259.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1227567112; called by muse, mutect2, varscan2
- TRANK1 | c.6829C>G p.R2277G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV57159200; called by muse, mutect2, varscan2
- TRIML2 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV58718343; called by muse, mutect2, varscan2
- TSPOAP1 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV52114393; called by muse, mutect2, varscan2
- TTC23 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV50443303, COSV50443411; called by muse, mutect2, varscan2
- TXNDC2 | c.611C>T p.P204L (on ENST00000306084 / NM_001098529.2; = p.P137L on NM_032243.6) | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV60154732; called by muse, mutect2, varscan2
- TYR | c.1484T>A p.L495H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.733); catalogued as COSV54482120; called by muse, mutect2, varscan2
- UBASH3B | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV52499332; called by muse, mutect2, varscan2
- UMOD | c.1183-1G>A p.X395_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV56778103; called by muse, mutect2, varscan2
- USP24 | c.1421A>T p.E474V | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53774472; called by muse, mutect2, varscan2
- USP26 | c.2027C>A p.P676H | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.762); catalogued as COSV100896531; called by muse, mutect2, varscan2
- USP26 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.734); catalogued as COSV100896533; called by muse, mutect2, varscan2
- VCAN | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54112449; called by muse, mutect2, varscan2
- VCAN | c.5966C>A p.P1989H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV54097409, COSV54112457; called by muse, mutect2, varscan2
- VCAN | c.7535A>T p.Y2512F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV54112464; called by muse, mutect2, varscan2
- VPS9D1 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV66994992; called by muse, mutect2, varscan2
- VWA8 | c.3997C>T p.H1333Y | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV64998811; called by muse, mutect2, varscan2
- WNT10A | c.1078C>A p.R360S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111793, COSV51463325, COSV99297293; called by muse, mutect2, varscan2
- XIRP2 | c.5602C>A p.L1868I (on ENST00000628543; = p.L2043I on NM_152381.6) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV54721611; called by muse, mutect2, varscan2
- XKR9 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV68773307, COSV68773709; called by muse, mutect2, varscan2
- XPNPEP2 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64369837; called by muse, mutect2, varscan2
- ZAN | c.2541G>T p.M847I | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61812829; called by muse, mutect2, varscan2
- ZEB2 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57962339; called by muse, mutect2, varscan2
- ZFHX4 | c.4073C>A p.S1358* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99255602; called by muse, mutect2, varscan2
- ZNF426 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53470140; called by muse, mutect2, varscan2
- ZNF480 | c.199G>T p.G67* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs891664427, COSV57997443; called by muse, mutect2, varscan2
- ZNF496 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54174957, COSV54180417; called by muse, mutect2, varscan2
- ZNF536 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62830354; called by muse, mutect2, varscan2
- ZNF804A | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56462048; called by muse, mutect2, varscan2
- ZNF804A | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100166284, COSV56443195; called by muse, mutect2, varscan2
- ZNF804A | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100166289, COSV56440215; called by muse, mutect2, varscan2
- ARHGAP31 | c.766dup p.R256Pfs*6 | Frame Shift Ins (INS) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- BAZ2B | c.1311del p.F438Sfs*5 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- BCORL1 | c.309del p.N104Tfs*12 | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | called by mutect2, pindel, varscan2
- C8A | c.1163del p.I388Kfs*63 | Frame Shift Del (DEL) | VAF 31/179 reads (17%) | called by mutect2, pindel, varscan2
- CBLL2 | c.15dup p.A6Cfs*3 | Frame Shift Ins (INS) | VAF 25/44 reads (57%) | called by mutect2, pindel, varscan2
- CEP128 | c.1165_1166insT p.E389Vfs*20 | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | called by mutect2, pindel*, varscan2
- HTR6 | c.1013del p.P338Hfs*116 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV3D-7 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- LRBA | c.6381_6382delinsT p.E2127Dfs*37 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by pindel, varscan2*
- MBD1 | c.257del p.R86Qfs*99 | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | called by mutect2, pindel, varscan2
- NF1 | c.6923_6927del p.D2308Afs*17 (on ENST00000358273 / NM_001042492.3; = p.D2287Afs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 56/311 reads (18%) | called by muse, mutect2, varscan2
- UNC13B | c.292_294delinsT p.T98Ffs*11 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by pindel, varscan2*
- ACSF2 | c.1518G>A p.V506= | Silent (SNP) | VAF 76/122 reads (62%) | catalogued as COSV51973637; called by muse, mutect2, varscan2
- ADAL | c.708C>T p.L236= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs112836130, COSV67501106; called by muse, mutect2, varscan2
- ADAMTS5 | c.1641C>T p.I547= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV53182691; called by muse, mutect2, varscan2
- AGMO | c.1083G>T p.S361= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs755873183, COSV61119575, COSV61119934; called by muse, mutect2, varscan2
- AHNAK | c.1770A>T p.T590= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV57223878; called by muse, mutect2, varscan2
- ANKRD17 | c.4077A>G p.L1359= | Silent (SNP) | VAF 77/195 reads (39%) | catalogued as COSV58225220; called by muse, mutect2, varscan2
- ARSI | c.660G>T p.L220= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV60818064; called by muse, mutect2, varscan2
- ATP1A2 | c.2316C>A p.S772= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV63405100, COSV63405757; called by muse, mutect2, varscan2
- C6orf15 | c.480A>T p.T160= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV52539167; called by muse, mutect2, varscan2
- CACNA1B | c.3348G>A p.V1116= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as COSV53123021; called by muse, mutect2, varscan2
- CACNA1S | c.2622G>T p.L874= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100754624; called by muse, mutect2, varscan2
- CAGE1 | c.2067C>A p.A689= (on ENST00000512086; = p.A553= on NM_205864.3) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV57080166; called by muse, mutect2, varscan2
- CAPN13 | c.516C>G p.A172= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV54433637; called by muse, mutect2
- CCDC74A | c.729G>T p.G243= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV54608458; called by muse, mutect2, varscan2
- CDH20 | c.984C>A p.P328= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV53014857; called by muse, mutect2, varscan2
- CDH7 | c.123G>T p.G41= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59890141, COSV59890763; called by muse, mutect2, varscan2
- CENPF | c.8502C>T p.T2834= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV65277407; called by muse, mutect2, varscan2
- CENPU | c.904C>T p.L302= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV55658117, COSV55658661; called by muse, mutect2, varscan2
- CHGB | c.381C>T p.G127= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs748338597, COSV66759819; called by muse, mutect2, varscan2
- CHL1 | c.1098C>A p.V366= (on ENST00000397491 / NM_001253387.1; = p.V382= on NM_006614.4) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56600733; called by muse, mutect2, varscan2
- CHRD | c.537G>A p.P179= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1282594969, COSV52610972; called by muse, mutect2, varscan2
- COL13A1 | c.276C>T p.V92= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as COSV62572822; called by muse, mutect2, varscan2
- COL18A1 | c.234C>T p.G78= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs537048520, COSV62705040, COSV62705276; called by muse, mutect2, varscan2
- CYBB | c.474G>A p.K158= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV66085944; called by muse, mutect2, varscan2
- DEFB112 | c.246A>T p.V82= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV59182899; called by muse, mutect2, varscan2
- DENND10 | c.598C>T p.L200= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV63858029; called by muse, mutect2
- DGKI | c.663C>T p.C221= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs1207049207, COSV55966540; called by muse, mutect2, varscan2
- DNAH8 | c.12963C>T p.F4321= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as COSV59468280; called by muse, mutect2, varscan2
- ELP4 | c.204A>C p.P68= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV53445758; called by muse, mutect2, varscan2
- EPHA5 | c.1050C>A p.P350= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as COSV99895909; called by muse, mutect2, varscan2
- F9 | c.676C>A p.R226= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as CM940544, CM940545, COSV54379802, COSV54381789; called by muse, mutect2, varscan2
- FBH1 | c.465A>T p.P155= (on ENST00000362091 / NM_178150.3; = p.P206= on NM_032807.4) | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV62983847; called by muse, mutect2, varscan2
- FGA | c.2229G>C p.R743= | Silent (SNP) | VAF 75/208 reads (36%) | catalogued as COSV57398897; called by muse, mutect2, varscan2
- FLT3 | c.1878C>T p.N626= | Silent (SNP) | VAF 87/177 reads (49%) | catalogued as rs757099771, COSV54063278; called by muse, mutect2, varscan2
- FRMPD1 | c.927G>T p.A309= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs766963520, COSV66701748; called by muse, mutect2, varscan2
- GPLD1 | c.2085C>T p.Y695= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs139070208; called by muse, mutect2, varscan2
- GRM5 | c.2502C>A p.R834= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV59618643; called by muse, mutect2, varscan2
- H3C7 | c.342C>T p.H114= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs1434074235, COSV55100543; called by muse, mutect2, varscan2
- HPSE2 | c.117C>T p.S39= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV100985038, COSV65196799; called by muse, mutect2, varscan2
- HR | c.2220T>A p.A740= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV57193750; called by muse, mutect2, varscan2
- HS3ST1 | c.183C>A p.G61= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1483731616, COSV50025036, COSV50027825; called by muse, mutect2, varscan2
- HTR2C | c.456G>T p.R152= | Silent (SNP) | VAF 57/79 reads (72%) | catalogued as COSV52219956; called by muse, mutect2, varscan2
- HUNK | c.513C>T p.I171= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV54228521; called by muse, varscan2
- IGSF5 | c.345C>A p.P115= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV66031024, COSV66031818; called by muse, mutect2, varscan2
- INSM2 | c.1657C>A p.R553= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV51891321; called by muse, mutect2, varscan2
- IQGAP2 | c.741G>A p.V247= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV57178263; called by muse, mutect2, varscan2
- IRX6 | c.166C>T p.L56= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV51861564; called by muse, mutect2, varscan2
- KCNB2 | c.1128C>A p.T376= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV73051773; called by muse, mutect2, varscan2
- KCNB2 | c.1449C>T p.D483= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as rs555669570, COSV73051774; called by muse, mutect2, varscan2
- KLHDC7A | c.2238G>A p.V746= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV68769008; called by muse, mutect2, varscan2
- KRT40 | c.222G>T p.V74= | Silent (SNP) | VAF 112/193 reads (58%) | catalogued as COSV66696301; called by muse, mutect2, varscan2
- LRRC41 | c.2112G>A p.L704= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV58441436; called by muse, mutect2
- LRRC8D | c.1950C>T p.I650= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV61580543; called by muse, mutect2, varscan2
- MACF1 | c.19125C>G p.L6375= (on ENST00000372915; = p.L4420= on NM_012090.5) | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV57113457, COSV57134623; called by muse, mutect2, varscan2
- MAN2A2 | c.57C>T p.V19= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as COSV64639357; called by muse, mutect2, varscan2
- MAP1B | c.5901C>T p.P1967= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs767226026, COSV57096886, COSV57097628; called by muse, mutect2, varscan2
- MED13L | c.6549G>T p.P2183= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV56115152, COSV56126211; called by muse, mutect2, varscan2
- MMRN1 | c.3351C>A p.I1117= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV53340850; called by muse, mutect2, varscan2
- MUC6 | c.1539C>A p.P513= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV101424393; called by muse, mutect2, varscan2
- MVP | c.537C>T p.R179= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV62422965; called by muse, mutect2
- NETO1 | c.1041C>A p.G347= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV55011827; called by muse, mutect2, varscan2
- NLRC4 | c.810C>A p.R270= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV61594039; called by muse, mutect2, varscan2
- NPAP1 | c.402G>T p.A134= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV61505707, COSV61509662, COSV61512243; called by muse, mutect2, varscan2
- NUDT9 | c.201G>A p.T67= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs752948509, COSV56197541; called by muse, mutect2, varscan2
- OGT | c.2214C>T p.G738= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV65482031; called by muse, mutect2, varscan2
- OR10Q1 | c.921G>A p.R307= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV57471424; called by muse, mutect2, varscan2
- OR11H12 | c.591G>T p.G197= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs556572796; called by mutect2, varscan2
- OR2L13 | c.477A>T p.T159= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as rs777149314, COSV63558011; called by muse, mutect2, varscan2
- OR4F17 | c.24G>T p.L8= | Silent (SNP) | VAF 48/489 reads (10%) | catalogued as COSV58842129; called by muse, mutect2, varscan2
- OR52E2 | c.768C>A p.A256= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs1333837316, COSV58613145, COSV58613524; called by muse, mutect2, varscan2
- OR52E6 | c.624G>A p.L208= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV61432866; called by muse, mutect2, varscan2
- OR5L2 | c.765C>A p.I255= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as rs1344044341, COSV65724692; called by muse, mutect2, varscan2
- OR7A17 | c.192C>A p.S64= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100541557; called by muse, mutect2, varscan2
- OR8H2 | c.252G>A p.A84= | Silent (SNP) | VAF 20/475 reads (4%) | catalogued as COSV57943731; called by muse, mutect2
- OTOP1 | c.1824C>G p.V608= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV56395495, COSV99587180; called by muse, mutect2, varscan2
- PADI3 | c.874C>A p.R292= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100968413, COSV100968613, COSV64934999; called by muse, mutect2, varscan2
- PAPPA | c.4389C>T p.T1463= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV60288952; called by muse, mutect2
- PCDHA8 | c.1470G>C p.V490= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as rs1554139385, COSV65330242; called by muse, mutect2, varscan2
- PCDHB9 | c.2226C>T p.T742= | Silent (SNP) | VAF 127/249 reads (51%) | catalogued as rs782378401, COSV53381896; called by muse, mutect2, varscan2
- PITPNM3 | c.426G>T p.T142= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV52598310; called by muse, mutect2, varscan2
- PLXNB3 | c.2304C>A p.T768= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as COSV62800385; called by muse, mutect2, varscan2
- PRDM9 | c.2313A>T p.T771= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV57010656; called by muse, varscan2
- RAB3GAP1 | c.1269A>T p.P423= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV51486012; called by muse, mutect2, varscan2
- RYR3 | c.5121G>T p.G1707= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV66802542; called by muse, mutect2, varscan2
- SALL1 | c.1944C>T p.D648= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs764320248, COSV51761819; called by muse, mutect2, varscan2
- SCN1A | c.2535A>T p.V845= (on ENST00000303395 / NM_001202435.3; = p.V834= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57680651; called by muse, mutect2, varscan2
- SDK2 | c.5523C>T p.A1841= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV66192518; called by muse, mutect2
- SLITRK2 | c.1656C>T p.I552= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59427563; called by muse, mutect2, varscan2
- SPRY3 | c.513C>T p.N171= | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as rs777498579, COSV57143823; called by muse, mutect2
- SULT2A1 | c.546G>A p.L182= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV55765726; called by muse, mutect2, varscan2
- SYNE1 | c.25C>A p.R9= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs200346529, COSV55054396; called by muse, mutect2, varscan2
- TENM3 | c.4080G>T p.L1360= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1369287790, COSV69314957; called by muse, mutect2, varscan2
- TMEM81 | c.90C>T p.A30= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1435984989, COSV52706030; called by muse, mutect2, varscan2
- USH1C | c.1542C>A p.T514= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV50026648; called by muse, mutect2, varscan2
- ZIM3 | c.1035C>A p.S345= | Silent (SNP) | VAF 69/126 reads (55%) | catalogued as COSV54141730, COSV54144993; called by muse, mutect2, varscan2
- ZNF284 | c.1386G>A p.K462= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV69691464; called by muse, mutect2, varscan2
- ZNF646 | c.1572C>T p.I524= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs765212636, COSV56211531; called by muse, mutect2, varscan2
- AP003393.1 | n.890C>A | RNA (SNP) | VAF 50/91 reads (55%) | catalogued as COSV58227752; called by muse, mutect2, varscan2
- BTN2A3P | n.1766A>T | RNA (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- CD8A | c.*2C>A | 3'UTR (SNP) | VAF 19/201 reads (9%) | catalogued as COSV99374181; called by muse, mutect2
- CD8A | c.*1C>A | 3'UTR (SNP) | VAF 18/198 reads (9%) | catalogued as COSV99374184; called by muse, mutect2
- DCHS2 | n.5133G>T | RNA (SNP) | VAF 38/85 reads (45%) | catalogued as COSV61776940; called by muse, mutect2, varscan2
- HNF4A | c.1129+26G>T | Intron (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100291020; called by muse, mutect2, varscan2
- MBD2 | c.702+2054G>T | Intron (SNP) | VAF 70/164 reads (43%) | catalogued as COSV99839886; called by muse, mutect2, varscan2
- PKD1L2 | n.907C>T | RNA (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
